Somatic mutation profile of tumor specimen TCGA-85-A4JC-01A (aliquot TCGA-85-A4JC-01A-11D-A257-08) from TCGA case TCGA-85-A4JC, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.7 years (30,942 days).
Specimen TCGA-85-A4JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57b4dca8-84c4-4e64-83f3-22dc9b095763.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A4JC-10A (Blood Derived Normal), aliquot TCGA-85-A4JC-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7464ba3-93e5-49d9-a30a-1c9b3d3d8bc0

The open-access MAF lists 268 somatic variants for this specimen: 194 protein-altering or splice-affecting, 66 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 66, Nonsense Mutation 17, Splice Site 6, Frame Shift Ins 4, RNA 4, Frame Shift Del 3, Intron 2, Splice Region 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52660939, COSV52789715, COSV53470581; called by muse, mutect2, varscan2
- ABCA5 | c.2541A>G p.I847M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV101201031; called by muse, mutect2, varscan2
- ABLIM1 | c.2142+2C>G p.X714_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99521591; called by muse, mutect2
- ACIN1 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99399220; called by muse, mutect2, varscan2
- ACTRT1 | c.61T>C p.C21R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100947515; called by muse, mutect2, varscan2
- ACVR1C | c.825G>C p.Q275H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54646103, COSV99694437; called by muse, mutect2
- ADAM18 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99695065; called by muse, mutect2, varscan2
- ADCY9 | c.2310G>T p.E770D | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV99569538; called by muse, mutect2, varscan2
- ADGRL3 | c.1705G>T p.V569L (on ENST00000506720 / NM_001322402.2; = p.V501L on NM_015236.6) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101546909; called by muse, mutect2
- AKAP6 | c.3818A>G p.Y1273C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs750718164, COSV99799058; called by muse, mutect2, varscan2
- ALPK2 | c.5104C>G p.L1702V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV100864188; called by muse, mutect2, varscan2
- ANKRD12 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1246361049, COSV100040917, COSV100042184; called by muse, mutect2, varscan2
- APCDD1 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100789911; called by muse, mutect2, varscan2
- ARHGAP25 | c.1049A>G p.H350R (on ENST00000409202 / NM_001007231.3; = p.H342R on NM_014882.3) | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771173; called by muse, mutect2, varscan2
- ARHGAP35 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV101350770; called by muse, mutect2, varscan2
- BAZ2B | c.1802G>T p.S601I | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100600441; called by muse, mutect2
- BEND4 | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101549720; called by muse, mutect2
- BFSP1 | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs145017887, COSV64900388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.6101G>A p.R2034H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80358849, CM074720, COSV66452039; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / not provided; called by muse, mutect2, varscan2
- C2orf42 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100033746; called by muse, mutect2, varscan2
- CAPN6 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV100136756; called by muse, mutect2, varscan2
- CCDC150 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV99776600; called by muse, mutect2, varscan2
- CD2 | c.740A>T p.E247V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV101040302; called by muse, mutect2
- CD36 | c.983T>G p.L328R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99987262; called by muse, mutect2, varscan2
- CDH18 | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99932747; called by muse, varscan2
- CDH18 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV56975182; called by muse, varscan2
- CEMIP | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372603353; called by muse, mutect2
- CEP128 | c.2024G>T p.R675M | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.326); catalogued as COSV99823902; called by muse, mutect2, varscan2
- CEP135 | c.2771G>T p.R924I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV57260516; called by muse, mutect2, varscan2
- CFHR5 | c.1072A>G p.R358G | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV99888174; called by muse, mutect2
- CHKA | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99694053; called by muse, mutect2, varscan2
- CLEC5A | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.533); catalogued as COSV101407750, COSV69397074; called by muse, mutect2
- CLN8 | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100485993; called by muse, varscan2
- CNTRL | c.4240C>G p.H1414D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99441418; called by muse, mutect2, varscan2
- COL22A1 | c.4397G>T p.R1466L | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100276848, COSV57355925; called by muse, mutect2
- COL28A1 | c.1103G>C p.R368T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as COSV101258387; called by muse, mutect2, varscan2
- COL2A1 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100475741; called by muse, mutect2, varscan2
- COL5A2 | c.1758A>T p.K586N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100880063, COSV66406931; called by muse, mutect2, varscan2
- CPB2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.32); catalogued as rs374795711, COSV99472979; called by muse, mutect2, varscan2
- CRACD | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99948775; called by muse, mutect2, varscan2
- CTC1 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1195186497, COSV100236205; called by muse, mutect2, varscan2
- CTNND2 | c.2698C>A p.L900M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100473112; called by muse, mutect2
- CXorf21 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as COSV100973233; called by muse, mutect2, varscan2
- DDIAS | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231062; called by muse, mutect2, varscan2
- DEF6 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100359190; called by muse, mutect2, varscan2
- DGKB | c.1706A>T p.N569I | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV99337169; called by muse, mutect2, varscan2
- DHRS4 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100365788, COSV100365894; called by muse, mutect2, varscan2
- DHX36 | c.2452G>C p.D818H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV100273382; called by muse, mutect2, varscan2
- DIP2B | c.3662C>G p.S1221C | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56591813; called by muse, mutect2
- DNAH5 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99446171; called by muse, mutect2
- DYNC2H1 | c.5535G>C p.L1845F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100517816, COSV100517904; called by muse, mutect2, varscan2
- DYNC2LI1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99570944; called by muse, mutect2, varscan2
- EIF2B3 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.162); catalogued as COSV100838912; called by muse, mutect2, varscan2
- EMILIN2 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99598236; called by muse, mutect2, varscan2
- ENPP6 | c.702C>A p.N234K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57067118; called by muse, mutect2, varscan2
- ERBB4 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53511030, COSV99618360; called by muse, mutect2, varscan2
- FAM110A | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760001857, COSV99856663; called by muse, mutect2, varscan2
- FAM126B | c.1179C>G p.I393M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99627472; called by muse, mutect2, varscan2
- FAM161A | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as COSV100281168; called by muse, mutect2
- FBN1 | c.5419G>A p.E1807K | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV100354167; called by muse, mutect2, varscan2
- FRYL | c.7453G>A p.D2485N | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as COSV99976153; called by muse, mutect2, varscan2
- FSHR | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.522); catalogued as COSV58623451; called by muse, mutect2
- GHDC | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313536619, COSV100054557; called by muse, mutect2
- GMPPA | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs568570865, COSV100354539; called by muse, mutect2, varscan2
- GPATCH4 | c.208T>A p.W70R | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100576889; called by muse, mutect2, varscan2
- H2BC10 | c.263C>G p.S88W | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.332); catalogued as COSV100010032, COSV100010037; called by muse, mutect2, varscan2
- HEATR5B | c.2936C>G p.S979C | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99248589; called by muse, mutect2
- HFM1 | c.3251T>A p.L1084H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99645548; called by muse, mutect2, varscan2
- HSPA13 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99579930; called by muse, mutect2
- HTR7 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99519157; called by muse, mutect2, varscan2
- HTRA2 | c.791T>C p.F264S | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99239513; called by muse, mutect2, varscan2
- HUWE1 | c.6170A>C p.Q2057P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99471006; called by muse, mutect2, varscan2
- IFT80 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100424513; called by muse, mutect2, varscan2
- IKBKE | c.257T>C p.M86T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100898111; called by muse, mutect2, varscan2
- IL12RB1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as rs147766868, CM034615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCG | c.889-1G>C p.X297_splice | Splice Site (SNP) | VAF 27/223 reads (12%) | catalogued as rs761302234, COSV99502137; called by muse, mutect2, varscan2
- JAK2 | c.1056G>T p.L352= | Splice Region (SNP) | VAF 8/48 reads (17%) | catalogued as COSV101071060; called by muse, mutect2, varscan2
- KCNB1 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as COSV100870401; called by muse, mutect2, varscan2
- LRP12 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV99407336; called by muse, mutect2
- LRRC7 | c.1633T>C p.W545R (on ENST00000651989 / NM_001370785.2; = p.W512R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.034); catalogued as rs1406985430, COSV50506082; called by muse, mutect2, varscan2
- LRRK2 | c.938T>A p.L313H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109488; called by muse, mutect2, varscan2
- MAGEB16 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101303286; called by muse, mutect2
- MAP2 | c.3524G>A p.C1175Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV99558426; called by muse, mutect2
- MAP3K8 | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.242); catalogued as COSV99551983; called by muse, mutect2, varscan2
- MS4A12 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV99188519; called by muse, mutect2
- MS4A12 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 11/178 reads (6%) | catalogued as COSV99188520; called by muse, mutect2
- MS4A13 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV100981054; called by muse, mutect2, varscan2
- MTCL1 | c.5029G>A p.V1677M (on ENST00000306329 / NM_001378206.1; = p.V1358M on NM_015210.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs116331286, COSV100093738; called by muse, mutect2, varscan2
- MTIF2 | c.1748A>T p.Q583L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.598); catalogued as COSV99703036; called by muse, mutect2, varscan2
- MYEF2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99981286; called by muse, mutect2
- MYH13 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV99352724; called by muse, mutect2, varscan2
- MYLK2 | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.289); catalogued as COSV101044680; called by muse, mutect2
- MYPN | c.3380G>C p.G1127A | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589670, COSV62733233; called by muse, mutect2, varscan2
- NAV3 | c.2372C>G p.S791C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV57088080, COSV99887878; called by muse, mutect2
- NCSTN | c.315-1G>A p.X105_splice | Splice Site (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99666887; called by muse, mutect2, varscan2
- NDC1 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV99323360; called by muse, mutect2, varscan2
- NEK11 | c.1824G>C p.L608F | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748872247, COSV101272975; called by muse, mutect2, varscan2
- NF1 | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as CM001256, COSV62212713; called by muse, mutect2, varscan2
- NOC3L | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100993279; called by muse, mutect2, varscan2
- NPFFR2 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as COSV100440396; called by muse, mutect2, varscan2
- NPY2R | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100279509; called by muse, mutect2, varscan2
- NRXN1 | c.3661G>C p.G1221R | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100640008; called by muse, mutect2, varscan2
- OPN1LW | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1451624086, COSV100885028; called by muse, mutect2, varscan2
- OR2M5 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 62/456 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); catalogued as COSV100822754; called by muse, mutect2, varscan2
- OR4C46 | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs776942943, COSV100060417, COSV100060471; called by muse, mutect2
- OR4D9 | c.537C>A p.C179* | Nonsense Mutation (SNP) | VAF 25/181 reads (14%) | catalogued as rs145873782, COSV100259733; called by muse, mutect2, varscan2
- ORC1 | c.1787A>G p.H596R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs933618089, COSV100856613; called by muse, mutect2, varscan2
- PADI3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100968419; called by muse, mutect2
- PAPPA2 | c.1819T>A p.Y607N | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV100866601; called by muse, mutect2, varscan2
- PCDHGA2 | c.712A>T p.N238Y | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99533054; called by muse, mutect2, varscan2
- PHF14 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV101301781; called by muse, mutect2
- PIK3R4 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147025690; called by muse, mutect2, varscan2
- PJA2 | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100754330; called by muse, mutect2, varscan2
- PLA1A | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV99845748; called by muse, mutect2, varscan2
- PLCH1 | c.1703C>G p.T568S (on ENST00000340059 / NM_001130960.2; = p.T580S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as COSV100395942; called by muse, mutect2
- PLCH1 | c.136G>T p.E46* (on ENST00000340059 / NM_001130960.2; = p.E58* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | catalogued as COSV100395946, COSV58195843; called by muse, mutect2, varscan2
- PLD2 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV99562100; called by muse, mutect2, varscan2
- PLEK | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.068); catalogued as COSV52252811, COSV99310794; called by muse, mutect2, varscan2
- POGLUT1 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99809866; called by muse, mutect2, varscan2
- POLR2B | c.1181A>G p.D394G | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107918; called by muse, mutect2, varscan2
- POTED | c.201C>G p.H67Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV100203045, COSV100203047; called by muse, mutect2
- PRDM1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1562174876, COSV64844363; called by muse, mutect2, varscan2
- PRDM9 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs781024869, COSV99689932; called by muse, mutect2, varscan2
- PSMC3IP | c.525G>C p.K175N (on ENST00000393795 / NM_016556.4; = p.K163N on NM_013290.6) | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99518786, COSV99519045; called by muse, mutect2, varscan2
- PSMC3IP | c.478G>C p.E160Q (on ENST00000393795 / NM_016556.4; = p.E148Q on NM_013290.6) | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV99518789; called by muse, mutect2, varscan2
- PSMC3IP | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1432607545, COSV53815869; called by muse, mutect2, varscan2
- PTDSS1 | c.1238A>T p.E413V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100428512; called by muse, mutect2, varscan2
- PTPRJ | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 46/307 reads (15%) | catalogued as COSV101394652; called by muse, mutect2, varscan2
- RAB6D | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV72151695; called by muse, mutect2, varscan2
- RANBP2 | c.9445G>C p.D3149H | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV99311478; called by muse, mutect2
- RBM14 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs779415955, COSV100036583; called by muse, mutect2
- RDH16 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100660074, COSV100660170; called by muse, mutect2, varscan2
- RIMS2 | c.4042G>T p.A1348S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99163575; called by muse, mutect2, varscan2
- RLF | c.811-1G>C p.X271_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as COSV101035146; called by muse, mutect2, varscan2
- RNF213 | c.1886T>C p.V629A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs754970367, COSV60626216; called by muse, mutect2, varscan2
- RNF213 | c.12268G>C p.E4090Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.025); catalogued as COSV100299905; called by muse, mutect2, varscan2
- RYR2 | c.12404G>T p.R4135L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63657848, COSV63684883; called by muse, mutect2, varscan2
- S100PBP | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV65110416; called by muse, mutect2, varscan2
- SCP2 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101026872; called by muse, mutect2, varscan2
- SENP2 | c.1448T>C p.V483A | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV99957633; called by muse, mutect2, varscan2
- SIK2 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 49/309 reads (16%) | catalogued as COSV100231944; called by muse, mutect2, varscan2
- SLC15A2 | c.1034A>T p.Q345L | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99815204; called by muse, mutect2, varscan2
- SLC30A6 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249333, COSV99249435; called by muse, mutect2
- SMAD4 | c.394C>G p.H132D | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61683986, COSV61688959, COSV61693892; called by muse, mutect2
- SNX15 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.698); catalogued as COSV100100866; called by muse, mutect2, varscan2
- SOAT1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100858897; called by muse, mutect2, varscan2
- SORCS3 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100864749; called by muse, mutect2, varscan2
- SPATA31D1 | c.3538A>G p.N1180D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100782558; called by muse, mutect2, varscan2
- SRSF4 | c.250+1G>C p.X84_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100861373; called by muse, mutect2, varscan2
- SRSF6 | c.675-1G>T p.X225_splice | Splice Site (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99719647; called by muse, mutect2, varscan2
- STK39 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV100596318; called by muse, mutect2, varscan2
- SVEP1 | c.2702C>G p.S901* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | catalogued as COSV100237480; called by muse, mutect2
- SYCP2 | c.3135G>C p.E1045D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV100698053; called by muse, mutect2
- SZT2 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100986970; called by muse, mutect2, varscan2
- TCTE1 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101025338, COSV65256166; called by muse, mutect2, varscan2
- TECPR2 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.134); catalogued as COSV100849879; called by muse, mutect2
- TEP1 | c.4390G>T p.G1464C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV99401831; called by muse, mutect2, varscan2
- TEP1 | c.4389G>T p.M1463I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99401833; called by muse, mutect2, varscan2
- TFAP2D | c.899T>A p.L300* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99145730; called by muse, mutect2
- TIMELESS | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV99973731; called by muse, mutect2, varscan2
- TNIK | c.3343C>T p.L1115F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455689; called by muse, mutect2
- TP53 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.375); catalogued as COSV52849333, COSV53297171, COSV53424484, COSV53438638; called by muse, mutect2, varscan2
- TP53TG5 | c.773A>C p.D258A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as COSV99713788; called by muse, mutect2, varscan2
- TRHDE | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as rs200482271, COSV53857265; called by muse, mutect2, varscan2
- TRIM10 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939651; called by muse, mutect2, varscan2
- TRIM60 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV100593936; called by muse, mutect2, varscan2
- TTN | c.56642G>C p.R18881T (on ENST00000591111; = p.R11457T on NM_003319.4) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | PolyPhen possibly damaging (0.836); catalogued as COSV100599112, COSV60166428; called by muse, mutect2, varscan2
- TTN | c.39826G>C p.E13276Q (on ENST00000591111; = p.E5852Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | PolyPhen possibly damaging (0.447); catalogued as COSV100599115; called by muse, mutect2
- TXNL1 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV54181721; called by muse, mutect2, varscan2
- UBXN7 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV99580901; called by muse, varscan2
- UQCRFS1 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV100508047; called by muse, mutect2, varscan2
- USH2A | c.11668C>A p.P3890T | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100230779; called by muse, mutect2, varscan2
- USH2A | c.1382C>A p.P461Q | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100230785; called by muse, mutect2, varscan2
- USP32 | c.4318G>C p.E1440Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.357); catalogued as COSV100341633; called by muse, varscan2
- USP53 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99917572; called by muse, mutect2, varscan2
- UST | c.807A>C p.R269S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV100819794; called by muse, mutect2, varscan2
- UTP20 | c.7216G>A p.V2406I | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99880976; called by muse, mutect2, varscan2
- WASHC5 | c.2211G>C p.L737F | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100572631; called by muse, mutect2, varscan2
- WDR35 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV99852930; called by muse, mutect2, varscan2
- XRN2 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101018105; called by muse, mutect2, varscan2
- ZDHHC9 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100852133; called by muse, mutect2, varscan2
- ZFYVE26 | c.1752C>G p.I584M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100720162; called by muse, varscan2
- ZNF600 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as COSV100592921; called by muse, mutect2, varscan2
- ZNF654 | c.2675C>G p.S892* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100525632; called by muse, mutect2, varscan2
- CLNK | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2
- DENND1B | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- GNG4 | c.106del p.Q36Rfs*58 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- LRRC7 | c.2440_2441dup p.N814Kfs*21 (on ENST00000651989 / NM_001370785.2; = p.N781Kfs*21 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 28/232 reads (12%) | called by mutect2, pindel, varscan2
- MAP3K11 | c.2496_2502del p.K833Wfs*112 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- MYH10 | c.637dup p.E213Gfs*3 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- PTEN | c.952_958dup p.L320Sfs*7 | Frame Shift Ins (INS) | VAF 19/123 reads (15%) | called by mutect2, varscan2
- SLC30A3 | c.745dup p.V249Gfs*72 | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- STAB2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM2A | c.492C>A p.I164= (on ENST00000219054; = p.I85= on NM_001308169.2) | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV99524980; called by muse, mutect2, varscan2
- ADAMTSL3 | c.396C>T p.A132= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99717441; called by muse, mutect2, varscan2
- AP5Z1 | c.462C>T p.L154= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs753077754, COSV100804025; called by muse, mutect2, varscan2
- ARHGAP15 | c.633T>C p.S211= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs775494512, COSV99709058; called by muse, mutect2, varscan2
- BAIAP2L1 | c.79C>T p.L27= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV99133793; called by muse, mutect2, varscan2
- CCNB1 | c.825C>T p.N275= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV99841229; called by muse, mutect2, varscan2
- CCND2 | c.633C>T p.I211= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs1488852838, COSV54223407; called by muse, mutect2, varscan2
- CD47 | c.294G>A p.L98= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as COSV100790099; called by muse, mutect2
- CELSR1 | c.3621C>T p.I1207= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99417175; called by muse, mutect2
- CHD6 | c.717A>T p.G239= | Silent (SNP) | VAF 57/366 reads (16%) | catalogued as COSV100497896; called by muse, mutect2, varscan2
- CLIP3 | c.1575G>A p.E525= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs754498816, COSV99430884, COSV99431274; called by muse, mutect2, varscan2
- CMYA5 | c.9303A>T p.A3101= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV101483939; called by muse, mutect2, varscan2
- COL6A3 | c.7800C>T p.G2600= | Silent (SNP) | VAF 19/205 reads (9%) | catalogued as rs963639269, COSV99796548; called by muse, mutect2
- CPA6 | c.51T>A p.L17= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV99912810; called by muse, mutect2
- DEFB136 | c.24A>G p.L8= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV101198595; called by muse, mutect2, varscan2
- DOCK9 | c.540G>T p.L180= (on ENST00000376460 / NM_001366676.2; = p.L181= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100238255; called by muse, mutect2, varscan2
- EPPK1 | c.666C>T p.P222= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as rs782273480, COSV101599822, COSV73260789; called by muse, mutect2
- ERBB4 | c.3408C>T p.A1136= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs200659841, COSV61534275; called by muse, mutect2, varscan2
- F5 | c.1278G>A p.Q426= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100888973, COSV63128103; called by muse, mutect2
- FMN2 | c.1245C>A p.T415= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100143608; called by muse, mutect2
- FREM2 | c.747G>T p.P249= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as COSV54828649, COSV99747370; called by muse, mutect2
- GBF1 | c.5166C>T p.V1722= (on ENST00000369983 / NM_001377137.1; = p.V1721= on NM_004193.3) | Silent (SNP) | VAF 64/329 reads (19%) | catalogued as rs781013460, COSV100890359; called by muse, mutect2, varscan2
- GPR155 | c.1008C>T p.F336= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99789736; called by muse, mutect2, varscan2
- GRK7 | c.543C>T p.F181= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as rs141991963, COSV53821732; called by muse, mutect2, varscan2
- HBEGF | c.99A>T p.L33= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs375401691; called by muse, mutect2
- HCN1 | c.1746C>A p.A582= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as COSV100299102; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.39A>T p.I13= | Silent (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- IL17A | c.453C>A p.V151= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV60683891; called by muse, mutect2, varscan2
- KDM8 | c.610A>C p.R204= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99619336; called by mutect2, varscan2
- KLHDC8A | c.339G>T p.L113= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV100903795; called by muse, mutect2, varscan2
- LEMD3 | c.1599G>A p.K533= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100384216; called by muse, mutect2
- LMO7 | c.4830C>T p.A1610= (on ENST00000357063; = p.A1291= on NM_005358.5) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs763979347, COSV100412639; called by mutect2, varscan2
- LNX2 | c.663A>G p.Q221= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs772179576, COSV100310540; called by muse, mutect2, varscan2
- MDN1 | c.4119G>C p.A1373= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV101020892, COSV65520031; called by muse, mutect2
- MPP2 | c.270C>T p.N90= (on ENST00000461854 / NM_001278372.2; = p.N66= on NM_005374.5) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99290100; called by muse, mutect2, varscan2
- MS4A13 | c.246T>A p.T82= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100981052; called by muse, mutect2, varscan2
- NCOR2 | c.325C>A p.R109= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100656984; called by muse, mutect2, varscan2
- NPHP3 | c.681C>T p.T227= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100446660; called by muse, mutect2, varscan2
- OGDH | c.1053G>T p.L351= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV99758446; called by muse, mutect2, varscan2
- OR5H6 | c.165C>A p.I55= (on ENST00000642105; = p.I39= on NM_001005479.2) | Silent (SNP) | VAF 52/423 reads (12%) | catalogued as COSV101051750; called by muse, mutect2, varscan2
- PCDHGB5 | c.2064A>T p.L688= | Silent (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- PDK1 | c.1182A>T p.T394= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99961167; called by muse, mutect2, varscan2
- PGGHG | c.1914T>C p.F638= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV101164335; called by muse, mutect2, varscan2
- PKNOX2 | c.1200C>T p.I400= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100020326; called by muse, mutect2
- PLD2 | c.1260G>T p.L420= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV54007741, COSV99562101; called by muse, mutect2, varscan2
- PON3 | c.801G>A p.V267= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99672320; called by muse, mutect2, varscan2
- PRR7 | c.687C>G p.L229= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV52790152, COSV99445424; called by muse, mutect2
- PTPRZ1 | c.4116G>T p.G1372= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as COSV101099733, COSV66432394; called by muse, mutect2
- RAG2 | c.687G>T p.R229= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100271131; called by muse, mutect2, varscan2
- RELT | c.264A>C p.T88= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99292703; called by muse, mutect2, varscan2
- RYR2 | c.7656G>T p.V2552= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV100768677; called by muse, varscan2
- SEC14L3 | c.903C>T p.C301= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1332246942, COSV53179965, COSV99307009; called by muse, mutect2, varscan2
- SEMA5A | c.2478A>G p.P826= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV101227364, COSV66802600; called by muse, mutect2, varscan2
- SLC1A6 | c.286C>T p.L96= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV99693497; called by muse, mutect2, varscan2
- SLC23A3 | c.48C>T p.S16= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99840915; called by muse, mutect2, varscan2
- SLC30A5 | c.2214A>T p.L738= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV101173558; called by muse, mutect2, varscan2
- SPATA46 | c.708C>T p.S236= | Silent (SNP) | VAF 28/260 reads (11%) | catalogued as COSV62640540; called by muse, mutect2, varscan2
- SPDYC | c.633C>A p.L211= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV101017140; called by muse, mutect2
- STXBP1 | c.837G>A p.V279= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100964534; called by muse, mutect2, varscan2
- TARS2 | c.1971C>T p.I657= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV100681739; called by muse, mutect2, varscan2
- TBL2 | c.990G>A p.A330= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs199869642, COSV99979523; called by muse, mutect2, varscan2
- TFPI | c.603A>G p.Q201= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99258169; called by muse, mutect2, varscan2
- USH2A | c.6738C>A p.A2246= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as rs753800541, COSV100230781; called by muse, mutect2, varscan2
- USP34 | c.7515A>G p.A2505= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs763529801, COSV101276770; called by muse, mutect2, varscan2
- ZFYVE26 | c.1708C>T p.L570= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100720163, COSV61331961; called by muse, varscan2
- ZNF341 | c.2328G>A p.L776= (on ENST00000375200 / NM_001282935.1; = p.L769= on NM_032819.4) | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV61005571; called by muse, mutect2
- BTN2A3P | n.1557dup | RNA (INS) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- CARMIL3 | chr14:24048766 G>A | 5'Flank (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- DCHS2 | n.6723C>A | RNA (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100601315; called by muse, mutect2
- IGF2BP2 | c.240-18135C>G | Intron (SNP) | VAF 22/130 reads (17%) | catalogued as COSV99960292; called by muse, mutect2, varscan2
- LDB3 | c.896+6745C>A | Intron (SNP) | VAF 38/180 reads (21%) | catalogued as COSV99554848; called by muse, mutect2, varscan2
- MIR548I2 | n.60C>T | RNA (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- SNORD3B-2 | n.110G>C | RNA (SNP) | VAF 16/166 reads (10%) | catalogued as rs751882790; called by muse, mutect2, varscan2
- ZNF99 | c.*567C>A | 3'UTR (SNP) | VAF 8/64 reads (13%) | catalogued as COSV101233735; called by muse, mutect2, varscan2
